CCDI case PBCWHI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3f1d6f03-310b-48f6-bc08-8400eb6cfeba

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1HES: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1HF6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1HG2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
